Somatic mutation profile of tumor specimen TCGA-B5-A11V-01A (aliquot TCGA-B5-A11V-01A-11D-A10M-09) from TCGA case TCGA-B5-A11V, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 64.7 years (23,630 days).
Specimen TCGA-B5-A11V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5342093-05c7-40ea-b434-1afbb2aa1a96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11V-10A (Blood Derived Normal), aliquot TCGA-B5-A11V-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d8f267c-7824-4a86-a1a5-4aed0ea48a9f

The open-access MAF lists 62 somatic variants for this specimen: 50 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 42, Silent 12, Frame Shift Del 3, Nonsense Mutation 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.109T>G p.S37A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913228, COSV62688488, COSV62688537, COSV62706597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 33/80 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782603, CM109590, CM110122, CM132268, COSV100910106, COSV64289126, COSV64290825; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANK1 | c.5177C>T p.T1726M | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as rs200662932, COSV55876151; called by muse, mutect2, varscan2
- ANKLE2 | c.989G>A p.W330* | Nonsense Mutation (SNP) | VAF 426/742 reads (57%) | catalogued as COSV61708243; called by muse, mutect2, varscan2
- ARHGAP17 | c.2095C>T p.R699W (on ENST00000289968 / NM_001006634.3; = p.R621W on NM_018054.6) | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs756117910, COSV51505488; called by muse, mutect2, varscan2
- ARRDC4 | c.657A>C p.E219D | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.998); catalogued as COSV51418768; called by muse, mutect2, varscan2
- CAP2 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.088); catalogued as rs748611415, COSV57730751; called by muse, mutect2, varscan2
- CDH4 | c.2638G>A p.V880I | Missense Mutation (SNP) | VAF 103/161 reads (64%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); catalogued as rs780992540, COSV64644940; called by muse, mutect2, varscan2
- CDH8 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100183273, COSV54854133; called by muse, mutect2, varscan2
- CENPF | c.7284G>T p.E2428D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV65273303; called by muse, mutect2, varscan2
- CNR1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV62986694; called by muse, mutect2, varscan2
- CSNK2A2 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV52641316; called by muse, mutect2, varscan2
- CSPG4 | c.5290G>A p.E1764K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as rs745751249, COSV57892059; called by muse, mutect2, varscan2
- DUSP16 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | catalogued as COSV53806681; called by muse, mutect2, varscan2
- EML2 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs770233699, COSV55598112; called by muse, mutect2, varscan2
- ERBB3 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 155/259 reads (60%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.697); catalogued as COSV57248597; called by muse, mutect2, varscan2
- H3C12 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as COSV58152185; called by muse, mutect2, varscan2
- HIVEP3 | c.2479C>A p.Q827K | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV56011195; called by muse, mutect2, varscan2
- IGHMBP2 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54820723; called by muse, mutect2, varscan2
- IRX3 | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 66/302 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV61667952; called by muse, mutect2, varscan2
- KRT28 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60683947; called by muse, mutect2, varscan2
- MBD6 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 30/109 reads (28%) | catalogued as COSV60765011; called by muse, mutect2, varscan2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2, varscan2
- MUC5B | c.9716C>G p.A3239G | Missense Mutation (SNP) | VAF 486/1036 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.088); catalogued as COSV71590540; called by muse, mutect2, varscan2
- MYH8 | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs142181278; called by muse, mutect2, varscan2
- NAV2 | c.1753A>T p.S585C (on ENST00000396087 / NM_001244963.2; = p.S562C on NM_145117.5) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62317774; called by muse, mutect2, varscan2
- NCAPG2 | c.3070C>T p.R1024W | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs373650801; called by muse, mutect2, varscan2
- PALB2 | c.3364G>A p.D1122N | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs540276838, COSV55163291; called by muse, mutect2, varscan2
- PAPOLB | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 147/340 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.349); catalogued as rs867228239, COSV68199333; called by muse, mutect2, varscan2
- PCDHA12 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 89/203 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV56484405; called by muse, mutect2, varscan2
- PHF8 | c.536C>T p.T179I (on ENST00000357988 / NM_001184896.1; = p.T143I on NM_015107.3) | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV57678366, COSV57680030; called by muse, mutect2, varscan2
- PIGK | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV63061723; called by muse, mutect2
- POLR2B | c.599T>C p.M200T | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58899115; called by muse, mutect2, varscan2
- RGS9 | c.1963A>G p.T655A | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV52223674; called by muse, mutect2, varscan2
- SHANK3 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1469528649, COSV53184617; called by muse, mutect2, varscan2
- SNCG | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 168/364 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as COSV100813846, COSV62318012; called by muse, mutect2, varscan2
- SPATA31E1 | c.1585C>A p.P529T | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs1277646717, COSV57790055; called by muse, mutect2, varscan2
- SPTBN1 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.477); catalogued as rs747062361, COSV61686491; called by muse, mutect2, varscan2
- TBC1D25 | c.627C>G p.N209K | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV65123397; called by muse, mutect2, varscan2
- TENM4 | c.8303G>A p.R2768Q | Missense Mutation (SNP) | VAF 99/213 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs374118156, COSV53619514; called by muse, mutect2, varscan2
- TOM1L2 | c.1142G>A p.R381H (on ENST00000379504 / NM_001350333.2; = p.R331H on NM_001033551.3) | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs375549455; called by muse, mutect2, varscan2
- WDR64 | c.3200C>A p.P1067Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63793508; called by muse, mutect2, varscan2
- ZDHHC8 | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV57709348; called by muse, mutect2, varscan2
- ARID1B | c.2156del p.P719Rfs*13 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | called by mutect2, pindel, varscan2
- COL12A1 | c.8335C>G p.R2779G | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DNAH11 | c.9455del p.K3152Rfs*11 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- HIPK2 | c.22dup p.M8Nfs*20 | Frame Shift Ins (INS) | VAF 42/126 reads (33%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1191dup p.F398Lfs*6 (on ENST00000521381 / NM_181523.3; = p.F128Lfs*6 on NM_181504.4) | Frame Shift Ins (INS) | VAF 35/134 reads (26%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1734_1744del p.Q579Vfs*19 (on ENST00000521381 / NM_181523.3; = p.Q309Vfs*19 on NM_181504.4) | Frame Shift Del (DEL) | VAF 66/156 reads (42%) | called by mutect2, pindel, varscan2
- AP1M2 | c.465C>T p.N155= | Silent (SNP) | VAF 104/213 reads (49%) | catalogued as rs755619204, COSV51565999; called by muse, mutect2, varscan2
- DIP2A | c.1746C>T p.Y582= | Silent (SNP) | VAF 62/114 reads (54%) | catalogued as rs370695651; called by muse, mutect2, varscan2
- LIPA | c.1023C>T p.S341= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs747984396, COSV60328481; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRSAM1 | c.1371C>T p.F457= | Silent (SNP) | VAF 56/111 reads (50%) | catalogued as rs571925919, COSV55938859; called by muse, mutect2, varscan2
- MIEF2 | c.300G>A p.S100= | Silent (SNP) | VAF 65/269 reads (24%) | catalogued as rs139491020; called by muse, mutect2, varscan2
- OR6X1 | c.516C>A p.I172= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV60009486; called by muse, mutect2, varscan2
- RNF6 | c.657A>T p.S219= | Silent (SNP) | VAF 102/206 reads (50%) | catalogued as COSV60418056; called by muse, mutect2, varscan2
- RPL3L | c.558C>T p.N186= | Silent (SNP) | VAF 162/256 reads (63%) | catalogued as rs776348164, COSV51905687; called by muse, mutect2, varscan2
- SNX21 | c.468C>T p.I156= | Silent (SNP) | VAF 63/173 reads (36%) | catalogued as rs756609480, COSV54168710; called by muse, mutect2, varscan2
- ST14 | c.450C>T p.S150= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs755460482, COSV53832023; called by muse, mutect2, varscan2
- SYTL2 | c.2478G>A p.R826= (on ENST00000528231 / NM_001162951.2; = p.R802= on NM_032943.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/106 reads (48%) | catalogued as COSV60356684; called by muse, mutect2
- ZNF708 | c.747G>A p.E249= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs770639697, COSV63607056; called by muse, mutect2, varscan2
